Somatic mutation profile of tumor specimen TCGA-HT-7468-01A (aliquot TCGA-HT-7468-01A-11D-2024-08) from TCGA case TCGA-HT-7468, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 30.7 years (11,209 days).
Specimen TCGA-HT-7468-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b012e66b-3254-4562-9e2f-af2ccab0493d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7468-10A (Blood Derived Normal), aliquot TCGA-HT-7468-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b56d7dc6-a913-4761-a882-2cb5981b0167

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5161C>T p.R1721* | Nonsense Mutation (SNP) | VAF 23/192 reads (12%) | hotspot (GDC flag); catalogued as COSV61371260; called by muse, mutect2, varscan2
- CIC | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 38/52 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568504941, COSV50547203; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 31/85 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 41/87 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRL2 | c.480C>G p.C160W | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761033313, COSV54654476; called by muse, mutect2, varscan2
- BRSK2 | c.1730C>T p.T577M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs746735741, COSV57540427; called by muse, mutect2
- CFAP69 | c.1930G>A p.A644T | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.154); catalogued as COSV60184365; called by muse, mutect2, varscan2
- HROB | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs563980398, COSV55368847; called by muse, mutect2, varscan2
- JAK3 | c.2116G>T p.A706S | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as COSV71685644, COSV71685789; called by muse, mutect2, varscan2
- SCN11A | c.2581C>A p.Q861K | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV56566382; called by muse, mutect2, varscan2
- TNXB | c.3721C>T p.R1241C (on ENST00000647633; = p.R994C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs201292165; called by muse, mutect2, varscan2
- NIPBL | c.6679_6682del p.V2227Ifs*2 | Frame Shift Del (DEL) | VAF 21/56 reads (38%) | called by mutect2, pindel, varscan2
- SLC13A1 | c.1047G>A p.V349= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV52008473; called by muse, mutect2, varscan2
- TTN | c.71559C>T p.D23853= (on ENST00000591111; = p.D16429= on NM_003319.4) | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs370908118; ClinVar: uncertain significance / likely benign; called by muse, mutect2
